Somatic mutation profile of tumor specimen 0DJR1C from CCDI case PBBXJZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Ganglioglioma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 9.0 years (3,291 days).
Specimen 0DJR1C: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fa5adb74-c780-45a2-bfe4-253bb39439f3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DJQZH (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f9ca8a1b-09df-40d7-abc5-758bf124d93b

The open-access MAF lists 6 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Intron 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- E2F7 | c.1000C>T p.R334C | Missense Mutation (SNP) | VAF 28/378 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775384926; called by muse, mutect2
- TOPAZ1 | c.1982G>A p.R661Q | Missense Mutation (SNP) | VAF 26/550 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.017); catalogued as rs900864389, COSV59070411; called by muse, mutect2
- LGSN | c.112C>A p.P38T | Missense Mutation (SNP) | VAF 25/326 reads (8%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); called by muse, mutect2
- SLITRK4 | c.2295C>A p.S765R | Missense Mutation (SNP) | VAF 26/468 reads (6%) | SIFT tolerated (0.65); PolyPhen benign (0.039); called by muse, mutect2
- PAPLN | c.2502C>T p.G834= (on ENST00000554301; = p.G807= on NM_173462.4) | Silent (SNP) | VAF 11/249 reads (4%) | catalogued as rs1053466217, COSV53720020; called by muse, mutect2
- USP28 | c.57+808C>A | Intron (SNP) | VAF 4/50 reads (8%) | called by muse, mutect2
